Gene-level copy-number profile of tumor specimen ALCH-B36O-TTP1-A from ALCHEMIST case ALCH-B36O, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.9 years (20,402 days).
Specimen ALCH-B36O-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b314305e-384b-46da-bcf0-041c85ca6ebf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B36O-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/59fb688e-9f5f-40ff-9c9f-d0ab8681e482

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 640; copy number 1: 13,992; copy number 2: 42,165; copy number 3: 1,921; copy number 4: 56; copy number 5: 131.

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:228,384,114–228,416,861, 6 genes: AL670729.2, TRIM11, AL670729.1, MIR6742, AL139288.1, TRIM17.
- chr2:130,151,392–130,182,750, 1 gene (within-gene range 0–2): SMPD4.
- chr5:100,388,853–100,389,938, 1 gene: AC113385.2.
- chr5:178,113,532–178,126,081, 1 gene: N4BP3.
- chr8:12,676,035–12,676,389, 1 gene: AC068587.1.
- chr8:144,330,565–144,416,844, 12 genes: SCRT1, SLC52A2, TMEM249, AC233992.2, FBXL6, ADCK5, CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4.
- chr9:124,481,236–124,516,056, 2 genes: NR5A1, AL354979.1.
- chr12:12,915,829–12,915,918, 1 gene (within-gene range 0–2): MIR614.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:29,113,050–29,331,304, 4 genes (within-gene range 0–2): AC009093.8, AC009093.10, AC009093.2, AC009093.7.
- chr16:46,469,341–46,698,394, 12 genes: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6.
- chr17:9,244,666–9,244,897, 1 gene: AC005695.3.
- chr17:22,090,743–22,266,392, 3 genes: UBBP4, FTLP13, LINC02002.
- chr19:22,596,257–22,623,971, 7 genes: GOLGA2P9, RN7SL860P, AC011467.3, AC011467.4, RAD54L2P1, LINC01785, AC011467.2.
- chr19:24,146,701–24,163,425, 2 genes: AC073534.2, AC073534.1.
- chr21:12,999,676–13,120,807, 5 genes: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 131 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:37,907,957–40,721,932, 131 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,730. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
